HCMI case HCM-EXPT-1071-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/6f9bbecc-fea5-4a66-b311-41dfb8956b8f

Demographics
Sex at birth: female; Age: 90 years or older (exact value withheld by GDC).

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Lobular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1071-C50-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1071-C50-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 92; Percent tumor nuclei: 95; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 3; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1071-C50-06A-01-S1-HE: Section location: Top; Percent tumor cells: 76; Percent tumor nuclei: 83; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 9; Percent lymphocyte infiltration: 27; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.
